Surgical pathology report (de-identified scan), TCGA case TCGA-A6-3808, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-3808-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Carcinoma right colon.

GROSS DESCRIPTION

Received fresh for tissue procurement labeled "right colon"

is a previously unopened 15 cm. segment of proximal right colon with attached 15 cm. distal ileum surfaced by smooth to scabrous tan pink serosa with a copious amount of attached mesocolon

and mesentery. No appendix is present. The proximal and distal margins measure 3.2 and 5.2 cm. in circumference respectively. On opening there is a well circumscribed, 4.4 x 4.0 cm. rubbery tan white-red tumor mass within the cecal pouch, 1 cm. distal to the ileocecal valve. A portion of tumor and a portion of normal are submitted for tissue procurement as requested. On sectioning, the tumor has a maximal thickness of 1.1 cm., grossly extending through the muscularis to within 0.1 cm. of the inked free serosal surface. The ileal mucosa and remaining colonic mucosa is unremarkable glistening tan pink with irregular folds and the walls average 0.5 cm. in thickness. Multiple soft pale tan to tan pink tissues in keeping with lymph nodes measuring up to 1.4 cm. in greatest dimension are recovered from the attached mesocolon and mesentery. Representative sections are submitted in 13 blocks as labeled. RS13.

BLOCK SUMMARY: 1 - Proximal and distal margins; 2-4 - tumor full thickness to inked free radial serosal surface; 5 - tumor to normal;
6 - ileum; 7 - ICB; 8 - colon; 9 and 10 - eight whole lymph nodes per cassette; 11 - six whole lymph nodes; 12 and 13 - one bisected lymph node per cassette.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma with mucinous differentiation.
Histologic grade: Moderately-differentiated.
Primary tumor (pT): Tumor invades through the muscularis propria into the pericolic fat (pT3).
Proximal margin: Negative.
Distal margin: Negative.
Circumferential (radial) margin: Negative.
Vascular invasion: Negative.
Regional lymph nodes (pN): 24 lymph nodes are negative for metastatic carcinoma (pN0).
Non-lymph node pericolic tumor: Absent.
Distant metastasis (pM): Cannot be assessed (pMx).

DIAGNOSIS

Colon, right and terminal ileum, resection:
Invasive moderately-differentiated colonic adenocarcinoma with mucinous differentiation extending through the wall of the colon into the pericolic fat.
The proximal, distal and radial margins of resection are free of tumor. Twenty four mesenteric lymph nodes are negative for metastatic carcinoma (0/24).

--- End Of Report ---

Source: NCI Genomic Data Commons file eaed6152-8964-4811-b015-a54bcfcc01da (TCGA-A6-3808.E1505F65-72EF-438D-A5E1-93ED8BF6635D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).